Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A94H, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-YU-A94H-01A (Primary Tumor).

100-3
Seminoma NOS 906113
Site (R) Testis NOS 062.9
JW 3/13/14

Collect date:

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Right testis

“Right testis”:

- Classic seminoma.
- Lesion size: 3.1cm.
- Intratubular germ cell neoplasia associated.
- Presence of necrotic areas.
- Tunica albuginea and rete testis compromised by neoplasia.
- Angiolymphatic invasion: not detected.
- Margin of surgical resection (spermatic cord): uninvolved by neoplasia.
- Epididymis, spermatic cord and tunica vaginalis uninvolved by neoplasia.
- Presence of adrenal ectopic tissue in paratesticular region.

NOTE:

- See Immunohistochemistry study.

Immunohistochemistry:

Morphologic findings associated with immunohistochemistry profile compatible with:

A8 – testicular lesion

Pure seminoma

A5 – Lesion in peritesticular adipose tissue:

Ectopic adrenal.

PATHOLOGIC STAGING

Topography	Morphology	Stage
Topic testis	Seminoma, NOS	pT1

Criteria	11/18/13	Yes	No
HPA Discrepancy			✓

Source: NCI Genomic Data Commons file 86bf6b8c-8833-4872-a7f4-91e27bc181c4 (TCGA-YU-A94H-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).